Somatic mutation profile of tumor specimen TCGA-BK-A6W3-01A (aliquot TCGA-BK-A6W3-01A-12D-A34Q-09) from TCGA case TCGA-BK-A6W3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 34.5 years (12,590 days).
Specimen TCGA-BK-A6W3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9974d09-38a3-4f95-9038-35cbd49bfea4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A6W3-10A (Blood Derived Normal), aliquot TCGA-BK-A6W3-10A-01D-A34Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37be7ae3-5d7c-48a3-b2ef-ca3dedbf6cfc

The open-access MAF lists 4,288 somatic variants for this specimen: 3,385 protein-altering or splice-affecting, 798 silent, 105 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,807, Silent 798, Nonsense Mutation 494, Splice Site 52, RNA 39, Intron 38, Splice Region 17, 5'Flank 11, 3'UTR 7, Frame Shift Ins 6, 3'Flank 5, 5'UTR 5.

Variants (750 of 4,288; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASNS | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as rs373645939; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.8494C>T p.R2832C | Missense Mutation (SNP) | VAF 29/83 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587779872, CM980159, COSV53732886, COSV53761977; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.3500G>T p.G1167V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587779578, CM950302, COSV100482640; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNA2 | c.2788C>T p.R930* (on ENST00000402739 / NM_001282597.3; = p.R882* on NM_004389.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as rs760139097, COSV58133839, COSV58164977; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DARS1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587776984, CM133675, COSV51537400; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.1081C>T p.R361C (on ENST00000399959; = p.R362C on NM_001356.5) | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs797045026, CM158053, COSV67863880; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.8197G>T p.E2733* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as rs1556764743, COSV100626229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.7657C>T p.R2553* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as rs398124050, CM040026, COSV58905803; ClinVar: pathogenic; called by muse, varscan2
- DYRK1A | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs797045041, COSV58292419; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GAN | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 20/32 reads (63%) | catalogued as rs119485090, CM020938, COSV101633963; ClinVar: pathogenic; called by muse, mutect2, varscan2
- JAG1 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as rs886043606, CM061812, COSV99652558; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3790G>T p.E1264* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as rs863224660, COSV62196635, COSV62202697; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NSDHL | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs587784223, COSV100938621; ClinVar: likely pathogenic / uncertain significance; called by mutect2, varscan2
- OTC | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs66550389, CM062966, CM062967, CM910275, COSV50000649, COSV50002957; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PEX1 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as rs201415996, COSV50395532; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PEX7 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as rs764924345, COSV100576462; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3073A>G p.T1025A | Missense Mutation (SNP) | VAF 6/32 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs397517202, CM126696, COSV55873252, COSV55911053, COSV55955422; ClinVar: pathogenic; called by muse, mutect2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 37/104 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as rs1060503077, CM030501, COSV57296425, COSV57317831; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AATF | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199725061; called by muse, mutect2, varscan2
- ABCA1 | c.5702G>T p.R1901I | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV66064710; called by muse, mutect2, varscan2
- ABCA12 | c.3289C>A p.H1097N (on ENST00000272895 / NM_173076.3; = p.H779N on NM_015657.3) | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV99788806; called by muse, mutect2, varscan2
- ABCA12 | c.2551A>C p.N851H (on ENST00000272895 / NM_173076.3; = p.N533H on NM_015657.3) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV99788809; called by muse, mutect2, varscan2
- ABCA13 | c.5300A>C p.E1767A | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV101329953, COSV70045683; called by muse, mutect2, varscan2
- ABCA13 | c.5870A>G p.E1957G | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV101329954; called by muse, mutect2, varscan2
- ABCA3 | c.1381G>A p.V461M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV100068143; called by muse, mutect2, varscan2
- ABCA5 | c.4568A>C p.K1523T | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376917230; called by muse, mutect2, varscan2
- ABCA5 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV101201034; called by muse, mutect2
- ABCA5 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 32/99 reads (32%) | catalogued as rs140653807, COSV101201035, COSV67015773; called by muse, mutect2, varscan2
- ABCA6 | c.357A>C p.E119D | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV52644726, COSV99445996; called by muse, mutect2, varscan2
- ABCA7 | c.4806T>G p.F1602L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99565318; called by muse, mutect2, varscan2
- ABCA9 | c.3888G>T p.K1296N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV100382762; called by muse, mutect2
- ABCB1 | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1390637727, COSV55944962; called by muse, mutect2, varscan2
- ABCB4 | c.3307G>A p.D1103N (on ENST00000265723 / NM_018849.3; = p.D1096N on NM_000443.4) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs543477825, COSV55931779; called by muse, mutect2
- ABCB4 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | catalogued as COSV99709891; called by muse, mutect2, varscan2
- ABCB5 | c.3247G>T p.E1083* (on ENST00000404938 / NM_001163941.2; = p.E638* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as rs1333814179, COSV51704169; called by muse, mutect2, varscan2
- ABCC10 | c.3394C>T p.R1132* (on ENST00000372530 / NM_001198934.2; = p.R1104* on NM_033450.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as rs764123121, COSV99766856; called by muse, mutect2, varscan2
- ABCC2 | c.2892C>A p.F964L | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100966425; called by muse, mutect2, varscan2
- ABCD3 | c.1878G>T p.R626S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100931343; called by muse, mutect2, varscan2
- ABCG2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1272411168, COSV52948003; called by muse, mutect2, varscan2
- ABCG5 | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as rs1339151172, COSV99575211; called by muse, mutect2, varscan2
- ABHD15 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs201924599, COSV56194949; called by muse, mutect2, varscan2
- ABHD16A | c.1456T>C p.Y486H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV101013135; called by muse, mutect2, varscan2
- ABHD2 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.251); catalogued as rs758636497, COSV100756194; called by muse, mutect2, varscan2
- ABHD4 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.041); catalogued as rs746220551, COSV53530114; called by muse, mutect2, varscan2
- ABI3BP | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1005975720, COSV52551207; called by muse, mutect2, varscan2
- ABR | c.307G>A p.E103K (on ENST00000302538 / NM_021962.5; = p.E66K on NM_001092.5) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765419742, COSV99347590; called by muse, mutect2, varscan2
- ABRAXAS1 | c.877T>C p.F293L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99788410; called by muse, mutect2, varscan2
- ABRAXAS1 | c.641A>C p.K214T | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.943); catalogued as COSV100426755, COSV58949811; called by muse, mutect2, varscan2
- AC004922.1 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 26/62 reads (42%) | catalogued as COSV53556768; called by muse, mutect2, varscan2
- AC006059.2 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV100045263; called by muse, mutect2, varscan2
- AC011462.1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.168); catalogued as rs532361185, COSV54196848; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC020907.6 | c.77A>C p.K26T | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100032327; called by muse, mutect2, varscan2
- AC024598.1 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.067); catalogued as rs371278525, COSV60824183; called by muse, mutect2, varscan2
- AC090517.4 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 27/75 reads (36%) | catalogued as COSV99974171; called by muse, mutect2, varscan2
- AC100868.1 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs372434452, COSV51839518; called by muse, mutect2, varscan2
- ACAD11 | c.921C>A p.F307L | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768617080, COSV53899123; called by muse, mutect2, varscan2
- ACBD6 | c.284A>C p.K95T | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100852430; called by muse, mutect2, varscan2
- ACCSL | c.965G>A p.G322D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs188401793, COSV101122159; called by muse, mutect2, varscan2
- ACE | c.2612T>A p.L871Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1272138201, COSV99326562; called by muse, mutect2
- ACO1 | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100007812; called by muse, mutect2, varscan2
- ACOX1 | c.1587A>G p.A529= | Splice Region (SNP) | VAF 36/91 reads (40%) | catalogued as COSV99503367; called by muse, mutect2, varscan2
- ACOX2 | c.256C>A p.H86N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV100250034; called by muse, mutect2, varscan2
- ACOXL | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759410867, COSV100489963; called by muse, mutect2, varscan2
- ACP3 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as COSV100313208; called by muse, mutect2, varscan2
- ACSBG1 | c.1028A>T p.Q343L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99357099; called by muse, mutect2, varscan2
- ACSBG2 | c.1724A>G p.N575S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV99397253; called by muse, mutect2, varscan2
- ACSL3 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs1225801240, COSV62484587; called by muse, mutect2, varscan2
- ACSL5 | c.1015G>A p.D339N (on ENST00000354273; = p.D395N on NM_016234.3) | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755535386, COSV61129611, COSV61132190; called by muse, mutect2, varscan2
- ACSL5 | c.1885G>T p.E629* (on ENST00000354273; = p.E685* on NM_016234.3) | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as rs755142676, COSV100634510; called by muse, mutect2, varscan2
- ACSM3 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1267372126, COSV55500169, COSV55502645; called by muse, mutect2, varscan2
- ACTL6A | c.1277G>T p.R426I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV99372889; called by muse, mutect2, varscan2
- ACTL7A | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs555458305, COSV61776457; called by muse, mutect2, varscan2
- ACTL8 | c.998G>T p.R333I | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV64860966; called by muse, mutect2, varscan2
- ACTL9 | c.1134C>A p.F378L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV61004586; called by muse, mutect2, varscan2
- ACTN4 | c.1665C>A p.F555L | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as COSV53145650; called by muse, mutect2, varscan2
- ACY3 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as rs200546996, COSV99662910; called by muse, mutect2, varscan2
- ADA | c.965T>C p.F322S | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100596087; called by muse, mutect2, varscan2
- ADAL | c.182G>T p.R61I | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101052500; called by muse, mutect2, varscan2
- ADAM17 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 33/91 reads (36%) | catalogued as COSV100176087; called by muse, mutect2, varscan2
- ADAM2 | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as COSV99696914; called by muse, varscan2
- ADAM21 | c.1119G>T p.E373D | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV99960650, COSV99961483; called by muse, mutect2, varscan2
- ADAM22 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as rs752694897, COSV55969207; called by muse, mutect2, varscan2
- ADAM29 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150256322; called by muse, varscan2
- ADAM29 | c.2231C>A p.P744H | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV100821931; called by muse, varscan2
- ADAM33 | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1236878819, COSV100597731; called by muse, mutect2, varscan2
- ADAMTS12 | c.2343A>C p.E781D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100710425; called by muse, mutect2
- ADAMTS16 | c.1208-1G>T p.X403_splice | Splice Site (SNP) | VAF 8/53 reads (15%) | catalogued as COSV57006561; called by muse, mutect2, varscan2
- ADAMTS20 | c.1282C>A p.H428N | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.801); catalogued as COSV101239034; called by muse, mutect2, varscan2
- ADAMTS3 | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 37/73 reads (51%) | catalogued as COSV54384393, COSV99710646; called by muse, mutect2, varscan2
- ADAMTS7 | c.3052G>T p.E1018* | Nonsense Mutation (SNP) | VAF 36/92 reads (39%) | catalogued as COSV101183036; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1132-1G>A p.X378_splice | Splice Site (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99646823; called by muse, mutect2, varscan2
- ADCY2 | c.1136A>G p.D379G | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100602070; called by muse, varscan2
- ADCY9 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as rs553450429, COSV99569544; called by muse, varscan2
- ADCYAP1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52485931; called by muse, mutect2, varscan2
- ADD1 | c.1503G>T p.E501D | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as COSV99296114; called by muse, mutect2, varscan2
- ADGRB3 | c.1823G>A p.R608K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.621); catalogued as COSV101000147, COSV65382174; called by muse, mutect2, varscan2
- ADGRB3 | c.1982G>A p.W661* | Nonsense Mutation (SNP) | VAF 27/61 reads (44%) | catalogued as COSV101000151, COSV65404877; called by muse, mutect2, varscan2
- ADGRG2 | c.1198G>T p.E400* (on ENST00000379869 / NM_001079858.3; = p.E397* on NM_005756.4) | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100491977; called by muse, mutect2, varscan2
- ADGRG2 | c.535G>T p.A179S (on ENST00000379869 / NM_001079858.3; = p.A176S on NM_005756.4) | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.103); catalogued as COSV100491982, COSV61338254; called by muse, varscan2
- ADGRG4 | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV99794687; called by muse, mutect2, varscan2
- ADGRG4 | c.4877C>T p.S1626F | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99794690; called by muse, mutect2, varscan2
- ADGRG4 | c.8134A>C p.N2712H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV99794694; called by muse, mutect2, varscan2
- ADGRL3 | c.485G>T p.R162I (on ENST00000506720 / NM_001322402.2; = p.R94I on NM_015236.6) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101546913; called by muse, mutect2, varscan2
- ADGRL3 | c.3002G>A p.R1001Q (on ENST00000506720 / NM_001322402.2; = p.R933Q on NM_015236.6) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.888); catalogued as rs370040630; called by muse, varscan2
- ADGRL4 | c.769G>T p.V257F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV100875687, COSV66067156; called by muse, mutect2, varscan2
- ADGRL4 | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100875688, COSV66061500; called by muse, mutect2, varscan2
- ADGRV1 | c.6779G>A p.R2260Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs749204963, COSV101315594; called by muse, varscan2
- ADGRV1 | c.15674C>T p.S5225F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV101315596; called by muse, mutect2, varscan2
- ADH7 | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV99265100; called by muse, mutect2
- ADIPOR2 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1273077347, COSV100840052; called by muse, mutect2, varscan2
- ADK | c.763-1G>T p.X255_splice (on ENST00000286621; = p.X238_splice on NM_001123.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV54218393; called by muse, varscan2
- ADNP | c.1492T>G p.L498V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.692); catalogued as COSV100823664; called by muse, varscan2
- ADNP | c.1461T>G p.F487L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.909); catalogued as COSV100823665; called by muse, varscan2
- ADORA2A | c.771C>A p.F257L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100417872; called by muse, mutect2, varscan2
- ADPGK | c.693C>A p.F231L | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV100295164; called by muse, mutect2, varscan2
- ADPRH | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs150984649, COSV63695504; called by muse, mutect2, varscan2
- ADPRM | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs150191988; called by muse, mutect2, varscan2
- ADRA2A | c.281A>G p.D94G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99701507; called by muse, mutect2, varscan2
- ADRA2A | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54529039; called by muse, mutect2, varscan2
- ADRA2B | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101337347; called by muse, mutect2, varscan2
- AFF2 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782378680, COSV53977676; called by muse, mutect2
- AFG1L | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100933877; called by muse, mutect2, varscan2
- AFG3L2 | c.1922G>T p.R641I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV99301602; called by muse, mutect2, varscan2
- AFG3L2 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV99301605; called by muse, mutect2, varscan2
- AFP | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV99889782, COSV99890019; called by muse, mutect2, varscan2
- AGAP2 | c.1613A>T p.D538V (on ENST00000547588 / NM_001122772.2; = p.D202V on NM_014770.4) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99222472; called by muse, mutect2, varscan2
- AGAP4 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 71/198 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs782241076, COSV101432623; called by muse, mutect2, varscan2
- AGBL1 | c.2891C>A p.S964Y | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66858612; called by muse, mutect2, varscan2
- AGBL2 | c.615C>A p.F205L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1161902371, COSV100101408; called by muse, mutect2, varscan2
- AGL | c.4315C>A p.L1439I | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV99648675; called by muse, mutect2, varscan2
- AGO2 | c.152A>T p.K51I | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.56); catalogued as COSV99595352; called by muse, mutect2, varscan2
- AGTR2 | c.721A>G p.T241A | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100903545; called by muse, mutect2
- AHCTF1 | c.2224C>T p.R742* (on ENST00000366508; = p.R716* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 41/88 reads (47%) | catalogued as COSV58247086; called by muse, mutect2, varscan2
- AHCTF1 | c.1427C>T p.S476F (on ENST00000366508; = p.S450F on NM_015446.5) | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV100403279; called by muse, mutect2, varscan2
- AHCY | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as rs1450713730, COSV54153076; called by muse, mutect2, varscan2
- AHI1 | c.3410C>A p.S1137Y | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as COSV99662163; called by muse, mutect2, varscan2
- AHNAK | c.6201A>C p.E2067D | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV57215075, COSV99946100; called by muse, varscan2
- AHNAK | c.6150G>T p.K2050N | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99946106; called by muse, varscan2
- AICDA | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV57563841, COSV99983919; called by muse, mutect2, varscan2
- AIMP1 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 49/106 reads (46%) | catalogued as rs373122636; called by muse, mutect2, varscan2
- AK3 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100729401; called by muse, mutect2, varscan2
- AK9 | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.176); catalogued as COSV99572387; called by muse, mutect2, varscan2
- AKAP11 | c.3176C>A p.S1059Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV99213633; called by muse, mutect2, varscan2
- AKAP13 | c.862-1G>T p.X288_splice | Splice Site (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100773238; called by muse, mutect2, varscan2
- AKAP3 | c.1547T>G p.F516C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); catalogued as COSV99961869; called by muse, mutect2
- AKAP4 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.817); catalogued as rs782377975, COSV62074933; called by muse, mutect2, varscan2
- AKAP4 | c.151A>G p.N51D | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV100654192; called by muse, mutect2, varscan2
- AKAP7 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs140783900, COSV53835698; called by muse, mutect2, varscan2
- AKNAD1 | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100645385; called by muse, mutect2, varscan2
- AKT1 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100838028; called by muse, mutect2, varscan2
- AL592490.1 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.143); catalogued as rs1286066617, COSV69427818; called by muse, mutect2, varscan2
- ALAD | c.61A>G p.T21A | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1479830405, COSV99474623; called by muse, mutect2, varscan2
- ALB | c.1376G>C p.S459T | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99890954; called by muse, mutect2, varscan2
- ALDH1L2 | c.2600C>T p.A867V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.737); catalogued as rs1207898463, COSV99310787; called by muse, mutect2, varscan2
- ALDH1L2 | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.608); catalogued as COSV51555701; called by muse, mutect2, varscan2
- ALK | c.3982A>G p.M1328V | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV101201454; called by muse, mutect2, varscan2
- ALK | c.3481G>A p.E1161K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs145194836; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV101201456, COSV101202614; called by muse, mutect2, varscan2
- ALOX15B | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs768198349, COSV101205582; called by mutect2, varscan2
- ALOX5AP | c.288G>T p.K96N | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100996269; called by muse, mutect2, varscan2
- ALPK1 | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 20/44 reads (45%) | catalogued as rs1388112183, COSV51581917; called by muse, mutect2, varscan2
- ALPP | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.528); catalogued as rs766110386, COSV101235110; called by muse, mutect2, varscan2
- AMD1 | c.325-1G>T p.X109_splice | Splice Site (SNP) | VAF 28/85 reads (33%) | catalogued as COSV100924461, COSV64387244; called by muse, mutect2, varscan2
- AMD1 | c.839T>G p.F280C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.742); catalogued as COSV100924463; called by muse, mutect2
- AMFR | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV51920352; called by muse, mutect2, varscan2
- AMIGO3 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.556); catalogued as COSV57537758; called by mutect2, varscan2
- AMY2B | c.9C>A p.F3L | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1252080358, COSV63715967, COSV63716962; called by muse, varscan2
- ANAPC10 | c.492G>T p.E164D | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.99); PolyPhen benign (0.01); catalogued as COSV100518626; called by muse, mutect2, varscan2
- ANAPC5 | c.1370G>A p.G457D | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.824); catalogued as COSV99946005; called by muse, mutect2, varscan2
- ANGEL1 | c.1618+1G>A p.X540_splice | Splice Site (SNP) | VAF 19/63 reads (30%) | catalogued as COSV99200336; called by muse, mutect2, varscan2
- ANGPT1 | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99862173; called by muse, mutect2, varscan2
- ANGPTL4 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as rs557133449, COSV56844285; called by muse, mutect2, varscan2
- ANK2 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1474105619, COSV52152842; called by muse, mutect2, varscan2
- ANK2 | c.6205C>T p.R2069C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as rs754572911, COSV52159875, COSV52189518; called by muse, mutect2, varscan2
- ANKAR | c.1267G>T p.E423* | Nonsense Mutation (SNP) | VAF 41/99 reads (41%) | catalogued as COSV99853967; called by muse, mutect2, varscan2
- ANKAR | c.3101G>A p.G1034E | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99853970; called by muse, mutect2, varscan2
- ANKFN1 | c.572G>T p.R191M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100593219, COSV59441784; called by muse, mutect2
- ANKRD12 | c.3635C>A p.S1212* | Nonsense Mutation (SNP) | VAF 38/71 reads (54%) | catalogued as COSV100040920; called by muse, mutect2, varscan2
- ANKRD13C | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1385933039, COSV99256387; called by muse, mutect2, varscan2
- ANKRD17 | c.1307C>G p.T436S | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100428681; called by muse, mutect2, varscan2
- ANKRD17 | c.429A>C p.E143D | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.036); catalogued as COSV58223631, COSV58227492; called by muse, mutect2, varscan2
- ANKRD22 | c.539T>G p.F180C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100905454; called by muse, mutect2
- ANKRD36 | c.445A>C p.K149Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV101347260; called by muse, mutect2, varscan2
- ANKRD50 | c.3869A>C p.N1290T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as COSV101538904; called by muse, mutect2, varscan2
- ANKS1B | c.1287G>T p.K429N | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.966); catalogued as COSV61376221; called by muse, mutect2, varscan2
- ANO2 | c.1060G>T p.E354* (on ENST00000356134 / NM_001278597.3; = p.E358* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as COSV100500058, COSV100502654; called by muse, varscan2
- ANO4 | c.2320C>A p.L774I (on ENST00000392977 / NM_001286615.2; = p.L739I on NM_178826.4) | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54587294; called by muse, mutect2, varscan2
- ANO5 | c.1335G>A p.E445= | Splice Region (SNP) | VAF 5/63 reads (8%) | catalogued as rs1231598963, COSV100201535, COSV61081911; called by muse, mutect2
- ANO5 | c.1933C>T p.R645W | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139303302; called by muse, mutect2, varscan2
- ANO6 | c.2549T>G p.F850C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV100262595; called by muse, mutect2, varscan2
- ANTXR2 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761958936, COSV56313905; called by muse, mutect2, varscan2
- ANXA13 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.333); catalogued as rs367659079, COSV51621713; called by muse, mutect2, varscan2
- ANXA8L1 | c.210C>T p.D70= | Splice Region (SNP) | VAF 37/211 reads (18%) | catalogued as rs1425924114; called by muse, mutect2, varscan2
- AOC1 | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); catalogued as COSV100710657; called by muse, mutect2, varscan2
- AP1G1 | c.844A>C p.K282Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV100250142; called by muse, mutect2, varscan2
- AP2A1 | c.1483A>C p.N495H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.4); catalogued as COSV100756164; called by muse, mutect2, varscan2
- AP2M1 | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV99490423; called by muse, mutect2, varscan2
- APBB2 | c.1585C>T p.R529* (on ENST00000295974 / NM_001166050.2; = p.R530* on NM_004307.2) | Nonsense Mutation (SNP) | VAF 32/35 reads (91%) | catalogued as rs757146916, COSV55946364; called by muse, mutect2, varscan2
- APC | c.4444C>A p.L1482I | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.967); catalogued as rs1313356706, COSV57354300, COSV99965977; called by muse, mutect2, varscan2
- APOB | c.8841T>G p.S2947R | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.576); catalogued as COSV99264204; called by muse, mutect2
- APOB | c.1975C>A p.L659I | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.65); catalogued as COSV99264206; called by muse, mutect2, varscan2
- APOBEC2 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as COSV99775315; called by muse, mutect2, varscan2
- APOBEC3D | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as rs765057107, COSV53325807; called by muse, mutect2, varscan2
- APOBEC4 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as rs141963987; called by muse, mutect2, varscan2
- APOBR | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as COSV100112339; called by muse, mutect2, varscan2
- APOC2 | c.265T>C p.F89L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV99376908; called by muse, mutect2, varscan2
- APOL5 | c.453G>T p.M151I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV99968343; called by muse, mutect2, varscan2
- AQP12A | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs766055016, COSV100538663; called by muse, mutect2, varscan2
- ARAF | c.584A>G p.E195G | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV99283039; called by muse, mutect2, varscan2
- ARAP2 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs966987664, COSV58286766; called by muse, mutect2, varscan2
- ARAP2 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 17/30 reads (57%) | catalogued as COSV100394255; called by muse, mutect2, varscan2
- AREL1 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.662); catalogued as rs763464411, COSV100707582; called by muse, mutect2, varscan2
- ARFGEF2 | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 34/96 reads (35%) | catalogued as COSV100904089; called by muse, mutect2, varscan2
- ARFIP2 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs771258941, COSV99601442; called by muse, mutect2, varscan2
- ARG2 | c.116G>T p.R39I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV55776660; called by muse, mutect2, varscan2
- ARGLU1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs1467963930, COSV62271553; called by muse, mutect2, varscan2
- ARHGAP11B | c.456G>T p.K152N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as rs1421479155, COSV70288336; called by muse, mutect2, varscan2
- ARHGAP22 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.657); catalogued as rs763749142, COSV99984654; called by muse, mutect2, varscan2
- ARHGAP24 | c.686A>G p.E229G (on ENST00000395184 / NM_001025616.3; = p.E136G on NM_031305.3) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV99981890; called by muse, mutect2, varscan2
- ARHGAP25 | c.367C>T p.R123C (on ENST00000409202 / NM_001007231.3; = p.R116C on NM_014882.3) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs201820537, COSV99771177; called by muse, mutect2, varscan2
- ARHGAP25 | c.1696G>T p.E566* (on ENST00000409202 / NM_001007231.3; = p.E558* on NM_014882.3) | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99771186; called by muse, mutect2, varscan2
- ARHGAP26 | c.1717G>T p.D573Y | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs775284912, COSV50832978, COSV99189530; called by muse, mutect2, varscan2
- ARHGAP32 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59843113; called by muse, mutect2, varscan2
- ARHGAP32 | c.38A>G p.D13G | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); catalogued as COSV100087171; called by muse, mutect2, varscan2
- ARHGAP4 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1569546003, COSV100604122, COSV63130805; called by muse, mutect2, varscan2
- ARHGAP44 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | catalogued as COSV52398793, COSV52406061; called by muse, mutect2, varscan2
- ARHGAP45 | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1292183410, COSV53125178; called by muse, mutect2
- ARHGAP6 | c.765G>T p.K255N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV100272480, COSV57301527; called by muse, mutect2
- ARHGEF12 | c.3686G>T p.G1229V | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); catalogued as COSV100754734; called by muse, mutect2, varscan2
- ARHGEF15 | c.2180C>A p.S727Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100730000; called by muse, mutect2, varscan2
- ARHGEF25 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs1352758268, COSV99677637; called by muse, mutect2, varscan2
- ARHGEF35 | c.1216T>C p.S406P | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100967681; called by muse, varscan2
- ARHGEF6 | c.1888C>A p.L630I | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51698271; called by muse, mutect2, varscan2
- ARHGEF9 | c.1477G>T p.E493* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as COSV99491475; called by muse, mutect2, varscan2
- ARID1A | c.3310G>T p.E1104* | Nonsense Mutation (SNP) | VAF 26/71 reads (37%) | catalogued as COSV100250639, COSV61378904; called by muse, mutect2, varscan2
- ARID2 | c.1366A>G p.M456V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs1565616545, COSV100535608; called by muse, mutect2, varscan2
- ARID4A | c.2214G>T p.K738N | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.264); catalogued as rs749862425, COSV100794087; called by muse, mutect2, varscan2
- ARID5B | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 25/73 reads (34%) | catalogued as COSV54420831; called by muse, mutect2, varscan2
- ARL13B | c.610G>T p.E204* (on ENST00000394222 / NM_001174150.2; = p.E97* on NM_144996.4) | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100115243; called by muse, mutect2, varscan2
- ARL4A | c.542A>G p.K181R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV100775890; called by muse, mutect2, varscan2
- ARL5A | c.47-1G>A p.X16_splice | Splice Site (SNP) | VAF 44/121 reads (36%) | catalogued as COSV99706552; called by muse, mutect2, varscan2
- ARMC12 | c.258G>T p.K86N (on ENST00000373866 / NM_001286574.2; = p.K113N on NM_145028.5) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV99849382; called by muse, mutect2, varscan2
- ARMC4 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV59456497; called by muse, mutect2, varscan2
- ARMC4 | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100536455; called by muse, mutect2, varscan2
- ARMC9 | c.92T>G p.F31C | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100589556; called by muse, mutect2, varscan2
- ARMCX5 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99863327; called by muse, mutect2, varscan2
- ARMH4 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as COSV99957789; called by muse, mutect2, varscan2
- ARNT | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55010856; called by muse, mutect2, varscan2
- ARNTL2 | c.930A>C p.K310N | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV99667583; called by muse, mutect2, varscan2
- ARSB | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs767794291, COSV99364454; called by muse, mutect2, varscan2
- ASAP3 | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 23/73 reads (32%) | catalogued as COSV100369256; called by muse, mutect2, varscan2
- ASB10 | c.59G>T p.R20I | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as COSV99318309; called by muse, mutect2, varscan2
- ASB15 | c.1589T>G p.I530R | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV99306306; called by muse, mutect2, varscan2
- ASB3 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs889327244, COSV55080018; called by muse, mutect2, varscan2
- ASH1L | c.1433T>C p.L478S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as COSV100853203; called by muse, mutect2, varscan2
- ASIC5 | c.1198C>A p.L400I | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV73333053; called by muse, mutect2, varscan2
- ASPN | c.601+1G>A p.X201_splice | Splice Site (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100978559; called by muse, mutect2, varscan2
- ASTE1 | c.1918T>A p.C640S | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV99393681; called by muse, mutect2, varscan2
- ASTL | c.1093A>G p.T365A | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV100668266; called by muse, mutect2, varscan2
- ASXL3 | c.3148G>A p.G1050R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99323824; called by muse, mutect2, varscan2
- ASXL3 | c.5039G>T p.R1680I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV99323826, COSV99323939; called by muse, mutect2, varscan2
- ATAD2 | c.3848C>A p.S1283Y | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99784228; called by muse, varscan2
- ATAD2 | c.2539C>T p.R847C | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1270279267, COSV54880131, COSV54880435; called by muse, mutect2, varscan2
- ATAD2 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 27/49 reads (55%) | catalogued as COSV54879934; called by muse, mutect2, varscan2
- ATAD2 | c.1649C>A p.S550Y | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375014962, COSV54886467; called by muse, mutect2, varscan2
- ATAD2B | c.2146A>C p.I716L | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99477133; called by muse, mutect2, varscan2
- ATF2 | c.334T>C p.S112P | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV99908467; called by muse, mutect2, varscan2
- ATG2B | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.492); catalogued as COSV100737778, COSV63421927; called by mutect2, varscan2
- ATM | c.3256C>T p.R1086C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.37); catalogued as rs201780199, COSV53773409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.7120G>T p.E2374* | Nonsense Mutation (SNP) | VAF 61/168 reads (36%) | catalogued as COSV53747187; called by muse, mutect2, varscan2
- ATP10A | c.2848G>T p.V950L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100790986; called by muse, mutect2, varscan2
- ATP10D | c.3905T>G p.V1302G | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV99905295; called by muse, mutect2, varscan2
- ATP12A | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs370861260; called by muse, mutect2, varscan2
- ATP13A3 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs375152534, COSV99756488; called by muse, varscan2
- ATP13A4 | c.3277G>T p.E1093* | Nonsense Mutation (SNP) | VAF 10/78 reads (13%) | catalogued as COSV100710145, COSV100710427; called by muse, mutect2, varscan2
- ATP2A3 | c.3014C>T p.S1005L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs186227171, COSV59228822; called by muse, mutect2, varscan2
- ATP2B3 | c.990G>T p.E330D | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV99683396; called by muse, mutect2, varscan2
- ATP4A | c.2830G>A p.D944N | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs772301702, COSV99382255; called by muse, mutect2, varscan2
- ATP4A | c.2211G>T p.K737N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV99382257; called by muse, mutect2, varscan2
- ATP6AP1 | c.1244C>G p.A415G | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100870660; called by muse, mutect2, varscan2
- ATP6V0D2 | c.561+1G>A p.X187_splice | Splice Site (SNP) | VAF 14/38 reads (37%) | catalogued as rs770305522, COSV99571449; called by muse, varscan2
- ATP6V1B2 | c.678T>G p.N226K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.19); catalogued as COSV99369286; called by muse, mutect2, varscan2
- ATP6V1C2 | c.38A>C p.K13T | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV99695590; called by muse, mutect2, varscan2
- ATP6V1H | c.1007A>C p.K336T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV100778617; called by muse, mutect2, varscan2
- ATP7A | c.830C>A p.S277* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100430419; called by muse, mutect2, varscan2
- ATP7A | c.1642G>T p.E548* | Nonsense Mutation (SNP) | VAF 42/103 reads (41%) | catalogued as COSV58445162; called by muse, mutect2, varscan2
- ATP7A | c.3601G>T p.D1201Y | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV100430426; called by muse, mutect2, varscan2
- ATP7B | c.1052G>T p.R351I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV99666147; called by muse, mutect2
- ATP8A1 | c.3153T>G p.F1051L | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100045314; called by muse, mutect2, varscan2
- ATP8A1 | c.653G>T p.R218I | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV52532802; called by muse, mutect2, varscan2
- ATP8A2 | c.438C>A p.D146E | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99680594; called by muse, mutect2, varscan2
- ATP8B1 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 29/66 reads (44%) | catalogued as COSV52173638; called by muse, mutect2, varscan2
- ATP8B4 | c.3093T>G p.I1031M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99464202; called by muse, mutect2, varscan2
- ATR | c.3536G>T p.R1179I | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100637777, COSV63392023; called by muse, mutect2, varscan2
- ATRN | c.2421G>T p.E807D | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV99496759; called by muse, mutect2, varscan2
- ATRNL1 | c.2445G>T p.K815N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100369628; called by muse, mutect2, varscan2
- ATRX | c.7012G>A p.A2338T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as COSV100970238; called by muse, mutect2, varscan2
- ATRX | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 31/67 reads (46%) | catalogued as COSV64881511; called by muse, mutect2, varscan2
- ATXN3 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61497978; called by muse, mutect2, varscan2
- ATXN3L | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV101019332; called by muse, mutect2, varscan2
- AUTS2 | c.810G>T p.K270N | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100715453; called by muse, mutect2, varscan2
- AXDND1 | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 7/71 reads (10%) | catalogued as COSV100858276; called by muse, mutect2
- AXDND1 | c.2509G>T p.E837* | Nonsense Mutation (SNP) | VAF 36/93 reads (39%) | catalogued as rs772723024, COSV100858277, COSV100858455; called by muse, mutect2, varscan2
- AXL | c.1778A>G p.D593G (on ENST00000301178 / NM_021913.5; = p.D584G on NM_001699.6) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV99996113; called by muse, mutect2, varscan2
- AZGP1 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs375716148; called by muse, mutect2, varscan2
- BAG2 | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.123); catalogued as COSV100443742; called by muse, mutect2, varscan2
- BANK1 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.624); catalogued as COSV100535975; called by muse, mutect2, varscan2
- BANK1 | c.808A>C p.I270L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV100535977; called by muse, varscan2
- BAP1 | c.224A>C p.D75A | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV56232999, COSV99963558; called by muse, mutect2, varscan2
- BARD1 | c.1619A>C p.K540T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV99638120; called by muse, varscan2
- BARD1 | c.1569-1G>A p.X523_splice | Splice Site (SNP) | VAF 28/60 reads (47%) | catalogued as COSV99638123; called by muse, varscan2
- BARD1 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758749603, COSV53613427; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ2B | c.4899T>G p.F1633L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.444); catalogued as COSV100600445; called by muse, mutect2, varscan2
- BBS12 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100044846; called by muse, mutect2, varscan2
- BBS4 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99166398; called by muse, mutect2, varscan2
- BBS4 | c.852G>T p.K284N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs12373005, COSV99166399; called by muse, mutect2, varscan2
- BBS7 | c.2124G>T p.L708F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99144838; called by muse, mutect2, varscan2
- BBX | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV57883835; called by muse, mutect2, varscan2
- BCAP31 | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs782083125, COSV100798892; called by muse, mutect2, varscan2
- BCAS3 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs773183785, COSV101175451; called by muse, varscan2
- BCAT2 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs372825449, COSV60271778; called by muse, mutect2, varscan2
- BCL10 | c.167C>A p.S56Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100997758; called by muse, mutect2, varscan2
- BCL2A1 | c.19G>T p.G7* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV99144320; called by muse, mutect2, varscan2
- BCL9L | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.049); catalogued as COSV100599627; called by muse, mutect2, varscan2
- BCLAF3 | c.675G>T p.E225D | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as COSV100503238; called by muse, varscan2
- BCLAF3 | c.380G>T p.R127M | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100503239; called by muse, mutect2, varscan2
- BCORL1 | c.3796C>T p.R1266* | Nonsense Mutation (SNP) | VAF 28/61 reads (46%) | catalogued as COSV54406822; called by muse, mutect2, varscan2
- BDNF | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs779034534, COSV59233109; called by muse, mutect2, varscan2
- BDP1 | c.4219C>A p.P1407T | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.087); catalogued as rs761577146, COSV100702829; called by muse, mutect2, varscan2
- BEST4 | c.518G>A p.S173N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.058); catalogued as COSV64733868; called by muse, mutect2, varscan2
- BFSP1 | c.1974G>T p.K658N | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100925324; called by muse, mutect2, varscan2
- BICC1 | c.1209T>G p.N403K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99570309; called by muse, mutect2, varscan2
- BIRC3 | c.735C>G p.Y245* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV99679750; called by muse, mutect2
- BIRC6 | c.5873G>A p.R1958Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs1239582999, COSV70204016; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.300A>C p.L100F | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.847); catalogued as COSV99958601; called by muse, mutect2, varscan2
- BLID | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.079); catalogued as COSV101601707; called by muse, mutect2, varscan2
- BLM | c.1310G>T p.G437V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100757034; called by muse, mutect2, varscan2
- BLNK | c.902+1G>T p.X301_splice | Splice Site (SNP) | VAF 14/90 reads (16%) | catalogued as COSV99813705; called by muse, mutect2, varscan2
- BMI1 | c.411C>A p.F137L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV64958895; called by muse, varscan2
- BMI1 | c.456G>T p.E152D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV100936337; called by muse, varscan2
- BMPER | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.052); catalogued as COSV99779113; called by muse, mutect2, varscan2
- BMPER | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.56); catalogued as rs767323516, COSV51818802; called by muse, mutect2, varscan2
- BMS1 | c.60G>T p.K20N | Missense Mutation (SNP) | VAF 96/250 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs375348243; called by muse, mutect2, varscan2
- BMX | c.192G>T p.E64D | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs756497600, COSV100564345; called by muse, mutect2, varscan2
- BMX | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.59); catalogued as rs947474924, COSV59590412; called by muse, mutect2, varscan2
- BMX | c.837C>A p.F279L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100564348; called by muse, mutect2
- BNC2 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66144492; called by muse, varscan2
- BNC2 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66146162; called by muse, varscan2
- BNIP3L | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV66077891; called by muse, mutect2, varscan2
- BPIFB1 | c.1331C>A p.S444Y | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV53608863, COSV99487608; called by muse, mutect2, varscan2
- BPIFC | c.579G>T p.K193N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.346); catalogued as COSV100300813; called by muse, mutect2, varscan2
- BRAP | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs151261185; called by muse, mutect2, varscan2
- BRCA2 | c.1250C>A p.S417Y | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101203997; called by muse, mutect2, varscan2
- BRD9 | c.801G>T p.K267N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV100056955; called by muse, mutect2, varscan2
- BRDT | c.736A>C p.K246Q | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.601); catalogued as COSV62863940; called by muse, mutect2
- BRDT | c.1457G>A p.R486K | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100746573; called by muse, mutect2
- BRINP1 | c.2058C>A p.F686L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.075); catalogued as COSV99774738; called by muse, mutect2, varscan2
- BRIP1 | c.1976A>C p.N659T | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.69); catalogued as COSV99369557; called by muse, mutect2, varscan2
- BRWD3 | c.2888C>T p.S963L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.069); catalogued as COSV64751280; called by muse, mutect2, varscan2
- BTAF1 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as rs753952218, COSV99794759; called by muse, mutect2, varscan2
- BTBD16 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs764340155, COSV53262181; called by muse, mutect2, varscan2
- BTBD8 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 25/62 reads (40%) | catalogued as COSV61546205; called by muse, mutect2, varscan2
- BTK | c.1321G>T p.E441* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | catalogued as CM960205, COSV100437383; called by muse, mutect2, varscan2
- BTK | c.501T>G p.I167M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.495); catalogued as COSV100437384; called by mutect2, varscan2
- BTN2A2 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1370809705, COSV100760256; called by muse, mutect2, varscan2
- BTN3A1 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs563390836, COSV50024627; called by muse, mutect2, varscan2
- C10orf53 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as COSV100935007; called by muse, mutect2, varscan2
- C10orf90 | c.860G>T p.R287I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99503309; called by muse, mutect2, varscan2
- C11orf49 | c.320T>G p.L107* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | catalogued as COSV99561769, COSV99561946; called by muse, mutect2, varscan2
- C12orf29 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100795048; called by muse, mutect2, varscan2
- C12orf60 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs977514400, COSV57452057; called by muse, mutect2, varscan2
- C12orf65 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.467); catalogued as rs777262448, COSV99473869; called by muse, mutect2, varscan2
- C12orf66 | c.646T>G p.L216V | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100320595; called by muse, mutect2, varscan2
- C14orf93 | c.1521G>T p.E507D | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as COSV52984515; called by muse, varscan2
- C16orf72 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV59916491; called by muse, mutect2, varscan2
- C17orf64 | c.602G>T p.R201I | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs1189425069, COSV99293376; called by muse, mutect2, varscan2
- C17orf64 | c.671G>T p.R224M | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV52257970; called by muse, mutect2, varscan2
- C19orf47 | c.261G>T p.M87I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1464451126, COSV100775031; called by muse, mutect2, varscan2
- C1GALT1C1 | c.217A>C p.I73L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV100485580; called by muse, mutect2
- C1QC | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759613063, COSV65890075; called by muse, mutect2, varscan2
- C1S | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.47); catalogued as rs781818479, COSV61072007; called by muse, mutect2, varscan2
- C1orf105 | c.157A>G p.N53D | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV99278161; called by muse, mutect2, varscan2
- C2CD5 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61722731; called by muse, mutect2, varscan2
- C2orf16 | c.1531C>A p.Q511K | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100820704; called by muse, mutect2, varscan2
- C2orf78 | c.500A>C p.K167T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV101280926; called by muse, mutect2, varscan2
- C3AR1 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1410112183, COSV99368190; called by muse, mutect2, varscan2
- C3orf33 | c.572C>A p.S191Y (on ENST00000340171 / NM_001308229.2; = p.S148Y on NM_173657.2) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100420026; called by muse, varscan2
- C3orf52 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV53497444, COSV99332343; called by muse, mutect2, varscan2
- C5 | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1402957355, COSV56324454; called by muse, mutect2, varscan2
- C5orf34 | c.1090T>G p.S364A | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV100175373; called by muse, mutect2, varscan2
- C6 | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); catalogued as COSV54722762; called by muse, mutect2, varscan2
- C7 | c.1005G>T p.K335N | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100495523, COSV57474578; called by muse, varscan2
- C7orf25 | c.1169T>G p.F390C | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.961); catalogued as COSV100623622; called by muse, mutect2
- C8B | c.692T>G p.L231* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100980713; called by muse, mutect2, varscan2
- CA8 | c.347G>T p.R116I | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as COSV100526726; called by muse, mutect2, varscan2
- CACNA1A | c.5671G>A p.A1891T | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs780366617, COSV100801484; called by muse, mutect2, varscan2
- CACNA1A | c.926T>G p.L309R | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100801486; called by muse, mutect2, varscan2
- CACNA1B | c.1584G>T p.E528D | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99495741; called by muse, mutect2, varscan2
- CACNA1C | c.5896C>T p.R1966* (on ENST00000399634 / NM_001167625.1; = p.R1895* on NM_000719.7) | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as rs1556290584, COSV59716172; called by muse, mutect2, varscan2
- CACNA1D | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55444993; called by muse, mutect2, varscan2
- CACNA1F | c.5603C>A p.S1868Y | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV100544482; called by muse, mutect2, varscan2
- CACNA1H | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760462130, COSV62006251; called by muse, mutect2, varscan2
- CACNA1H | c.1175C>A p.S392* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100671161, COSV61987990; called by muse, mutect2, varscan2
- CACNA2D1 | c.2066G>T p.R689I (on ENST00000356253 / NM_001366867.1; = p.R677I on NM_000722.4) | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100666224; called by muse, mutect2, varscan2
- CACNA2D2 | c.2112C>A p.F704L (on ENST00000479441 / NM_001174051.3; = p.F697L on NM_006030.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV99817075; called by muse, mutect2, varscan2
- CACNB4 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99137871; called by muse, mutect2, varscan2
- CACNG1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.385); catalogued as rs760216442, COSV56826298, COSV56827091; called by muse, varscan2
- CACNG7 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV99711884; called by muse, mutect2, varscan2
- CAD | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as rs775146460, COSV53028693; called by muse, mutect2, varscan2
- CAD | c.3843A>C p.E1281D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99254583; called by muse, mutect2, varscan2
- CADM1 | c.480G>T p.E160D | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.023); catalogued as COSV100522229; called by muse, mutect2
- CADPS2 | c.3736C>T p.R1246* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | catalogued as rs1354028382, COSV57349948, COSV57350326; called by muse, mutect2, varscan2
- CALCRL | c.1327G>T p.G443* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as COSV101130896, COSV66476489; called by muse, mutect2, varscan2
- CALD1 | c.1377A>T p.K459N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV100724074; called by muse, mutect2
- CALR3 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.063); catalogued as rs1442412253, COSV54172988; called by muse, mutect2, varscan2
- CAMK4 | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV56662944, COSV56675908; called by muse, mutect2, varscan2
- CAMSAP2 | c.1269C>A p.F423L (on ENST00000236925 / NM_001297707.2; = p.F412L on NM_203459.3) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV99372984; called by muse, mutect2, varscan2
- CAMSAP3 | c.3418G>T p.E1140* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as COSV50335313, COSV99350041; called by muse, mutect2, varscan2
- CAPN3 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs370422576; called by muse, mutect2, varscan2
- CAPNS2 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100044897, COSV50894557; called by muse, mutect2
- CAPNS2 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as rs1353990919, COSV100044514; called by muse, mutect2
- CAPS2 | c.1647G>T p.K549N | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV60824530; called by muse, mutect2, varscan2
- CAPS2 | c.842G>T p.R281I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV100157462; called by muse, mutect2, varscan2
- CAPZA2 | c.813G>T p.W271C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753853; called by muse, varscan2
- CARD18 | c.216T>G p.F72L | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.247); catalogued as COSV101596025; called by muse, mutect2, varscan2
- CARD6 | c.2187G>T p.E729D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54564464, COSV54568275, COSV99620425; called by muse, mutect2, varscan2
- CARD8 | c.739G>A p.E247K (on ENST00000651546 / NM_001184900.3; = p.E197K on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs542641676, COSV100751027; called by muse, mutect2, varscan2
- CARMIL3 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV100549361; called by muse, mutect2, varscan2
- CASP5 | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs1450468813, COSV99507289; called by muse, mutect2, varscan2
- CASP8 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as rs1339962485, COSV51846409, COSV51847390, COSV51855757; called by muse, mutect2, varscan2
- CASP8 | c.356C>A p.S119Y (on ENST00000432109 / NM_033355.3; = p.S151Y on NM_001228.4) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as COSV99964819; called by muse, mutect2, varscan2
- CASP8AP2 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.051); catalogued as rs758643574, COSV52746227; called by mutect2, varscan2
- CASP8AP2 | c.1966G>T p.E656* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV52745086, COSV99386833; called by muse, mutect2, varscan2
- CASP8AP2 | c.5505G>C p.K1835N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV52747944, COSV52748486; called by muse, mutect2, varscan2
- CASS4 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs767728589, COSV64386016; called by mutect2, varscan2
- CASS4 | c.1852G>T p.E618* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as COSV100824574; called by muse, mutect2, varscan2
- CATSPER3 | c.153C>A p.F51L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99253974; called by muse, mutect2, varscan2
- CATSPERB | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs768019574, COSV56434429; called by muse, mutect2, varscan2
- CATSPERD | c.1126C>A p.L376I | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV100486691; called by muse, mutect2, varscan2
- CATSPERE | c.931C>A p.R311S | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100834963, COSV100835081; called by muse, mutect2, varscan2
- CATSPERG | c.2899G>A p.E967K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.633); catalogued as rs147603617; called by muse, mutect2, varscan2
- CATSPERG | c.3146A>G p.Q1049R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV99286181; called by muse, mutect2, varscan2
- CAVIN4 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100293145; called by muse, varscan2
- CBL | c.416G>T p.R139I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50646215, COSV50656025; called by muse, mutect2, varscan2
- CBS | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as CM033354, COSV100657899; called by mutect2, varscan2
- CBX8 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as rs763836445, COSV99485775; called by muse, mutect2, varscan2
- CCBE1 | c.167A>C p.K56T | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1329446737, COSV101480337; called by muse, mutect2, varscan2
- CCDC102B | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs372574927; called by muse, mutect2, varscan2
- CCDC102B | c.1010C>A p.S337Y | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as COSV100102049, COSV100102573; called by muse, mutect2, varscan2
- CCDC110 | c.2260G>T p.E754* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100293735; called by muse, mutect2, varscan2
- CCDC125 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV67288452; called by muse, mutect2, varscan2
- CCDC126 | c.164G>T p.R55I | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV100277874; called by muse, mutect2, varscan2
- CCDC126 | c.248A>C p.K83T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV100277876; called by muse, mutect2, varscan2
- CCDC136 | c.2020C>T p.R674* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV52804518; called by muse, mutect2, varscan2
- CCDC144A | c.2714A>G p.N905S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.056); catalogued as COSV100138411; called by muse, mutect2, varscan2
- CCDC146 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.984); catalogued as rs201625834; called by muse, mutect2, varscan2
- CCDC15 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as rs201773360; called by muse, mutect2, varscan2
- CCDC150 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as rs368906039; called by muse, varscan2
- CCDC150 | c.2008C>A p.Q670K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.64); catalogued as COSV99776605; called by muse, mutect2, varscan2
- CCDC158 | c.2108C>A p.S703Y | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101187174, COSV66355933; called by muse, mutect2
- CCDC160 | c.280A>C p.N94H | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV100892093; called by muse, mutect2, varscan2
- CCDC160 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV100892094, COSV104426180; called by muse, mutect2, varscan2
- CCDC160 | c.857G>T p.R286I | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100892095; called by muse, mutect2
- CCDC171 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99900026; called by muse, mutect2, varscan2
- CCDC171 | c.1481A>C p.K494T | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV99900027; called by muse, mutect2, varscan2
- CCDC180 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758716537, COSV63831649; called by muse, mutect2, varscan2
- CCDC180 | c.1293G>T p.E431D | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV100826607; called by muse, mutect2, varscan2
- CCDC180 | c.3530C>A p.S1177Y | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as COSV100826608; called by muse, mutect2, varscan2
- CCDC180 | c.4307G>A p.R1436Q | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs956290540, COSV100826609; called by muse, mutect2, varscan2
- CCDC186 | c.2023G>T p.E675* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as COSV65160951; called by muse, mutect2, varscan2
- CCDC186 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs532080412, COSV100990995, COSV65159686; called by mutect2, varscan2
- CCDC22 | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 29/66 reads (44%) | catalogued as COSV100873098; called by muse, mutect2, varscan2
- CCDC27 | c.1602C>A p.S534R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV99622208; called by muse, mutect2, varscan2
- CCDC28B | c.164+1G>A p.X55_splice | Splice Site (SNP) | VAF 34/108 reads (31%) | catalogued as COSV99356360; called by muse, mutect2, varscan2
- CCDC33 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV100350781; called by muse, mutect2
- CCDC60 | c.1267T>G p.F423V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV100554758; called by muse, mutect2, varscan2
- CCDC63 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.127); catalogued as rs267603306, COSV57526980, COSV57531131; called by muse, mutect2, varscan2
- CCDC7 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as rs762095619, COSV53227495, COSV99511238; called by muse, mutect2, varscan2
- CCDC7 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.988); catalogued as rs747197679, COSV53228403; called by muse, mutect2, varscan2
- CCDC73 | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV58795276, COSV58798835; called by muse, mutect2, varscan2
- CCDC73 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100067072, COSV58797184; called by muse, mutect2, varscan2
- CCDC73 | c.376T>A p.L126I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100066698; called by muse, mutect2, varscan2
- CCDC83 | c.1232C>A p.S411Y (on ENST00000342404 / NM_001286159.2; = p.S442Y on NM_173556.5) | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs767082436, COSV54701866; called by muse, varscan2
- CCDC87 | c.1367C>A p.S456Y | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100039816; called by muse, mutect2, varscan2
- CCER1 | c.974C>A p.A325D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100726954; called by muse, mutect2, varscan2
- CCK | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100588997; called by muse, mutect2, varscan2
- CCL20 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV100721784; called by muse, mutect2, varscan2
- CCL25 | c.254G>T p.R85I | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV53664280, COSV99495099; called by muse, mutect2, varscan2
- CCM2L | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs778563139, COSV52950492, COSV99395164; called by muse, mutect2
- CCN1 | c.704C>A p.S235* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV101486121; called by muse, mutect2, varscan2
- CCNB3 | c.1857G>T p.K619N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV99328633; called by muse, mutect2, varscan2
- CCNJ | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs572418915, COSV99796193; called by muse, mutect2, varscan2
- CCNL1 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs906411651, COSV55818714; called by muse, mutect2, varscan2
- CCNT2 | c.151C>A p.L51I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99750264; called by muse, mutect2, varscan2
- CCPG1 | c.2169G>T p.E723D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as COSV51241203; called by muse, mutect2, varscan2
- CCSER1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs745548077, COSV100390706, COSV61437396; called by muse, mutect2, varscan2
- CCSER2 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs750250954, COSV56504046; called by muse, varscan2
- CCT3 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.113); catalogued as rs753353685, COSV55292727; called by muse, mutect2
- CCZ1B | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as rs1390943484, COSV57436729; called by muse, mutect2, varscan2
- CD163 | c.2947G>T p.E983* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100775733; called by muse, mutect2, varscan2
- CD163 | c.2628C>A p.N876K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100775734; called by muse, mutect2, varscan2
- CD164L2 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV100927578; called by muse, mutect2, varscan2
- CD200R1L | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV101236557; called by muse, mutect2, varscan2
- CD274 | c.408A>C p.K136N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.101); catalogued as COSV101055964; called by muse, mutect2, varscan2
- CD34 | c.494C>A p.S165Y | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.055); catalogued as COSV100178223; called by muse, mutect2, varscan2
- CD6 | c.1176G>T p.E392D | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV100532848; called by muse, mutect2, varscan2
- CDADC1 | c.1052G>T p.R351I | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.111); catalogued as COSV99212536; called by muse, mutect2, varscan2
- CDAN1 | c.2615G>T p.R872I | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62331498; called by muse, mutect2, varscan2
- CDC14B | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | catalogued as COSV99685392; called by muse, mutect2, varscan2
- CDC20B | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV57054383; called by muse, varscan2
- CDC37L1 | c.511A>G p.M171V | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV101116485; called by muse, mutect2
- CDC42BPA | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100504090; called by muse, varscan2
- CDC42BPA | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.774); catalogued as rs1437585356, COSV100504093; called by muse, mutect2, varscan2
- CDCP1 | c.212A>C p.K71T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.234); catalogued as COSV99943896; called by muse, mutect2, varscan2
- CDCP2 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs999292470, COSV100313366; called by muse, mutect2
- CDH10 | c.1369C>A p.L457I | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100050447; called by muse, mutect2, varscan2
- CDH10 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100050450; called by muse, varscan2
- CDH11 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs778660327; called by muse, mutect2
- CDH11 | c.1225G>T p.D409Y | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99217522; called by muse, mutect2, varscan2
- CDH11 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51753294; called by muse, mutect2, varscan2
- CDH12 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs772189448, COSV66392948; called by muse, mutect2
- CDH12 | c.462T>G p.N154K | Missense Mutation (SNP) | VAF 127/330 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101201815; called by muse, mutect2, varscan2
- CDH17 | c.1646C>A p.S549Y | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374501409, COSV50325497, COSV99217041; called by muse, mutect2, varscan2
- CDH18 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs771062780, COSV56912409, COSV56939656; called by muse, mutect2, varscan2
- CDH19 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs371688912; called by muse, varscan2
- CDH20 | c.1373C>A p.S458Y | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV53012389; called by muse, mutect2, varscan2
- CDH6 | c.33T>G p.F11L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99418313; called by muse, mutect2, varscan2
- CDH6 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54077621; called by muse, mutect2, varscan2
- CDH6 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs752932258, COSV54065993; called by muse, mutect2, varscan2
- CDH7 | c.162C>A p.F54L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV59894440; called by muse, mutect2
- CDH7 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59883306; called by muse, mutect2, varscan2
- CDH8 | c.1717C>A p.L573I | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as rs1263598585, COSV54851218; called by muse, mutect2, varscan2
- CDH8 | c.1597T>G p.Y533D | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100180016; called by muse, mutect2, varscan2
- CDHR1 | c.1896G>T p.K632N | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV100258544; called by muse, mutect2, varscan2
- CDK17 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1255337861, COSV54130607, COSV99702521; called by muse, mutect2, varscan2
- CDK9 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100953627; called by muse, mutect2, varscan2
- CDKL2 | c.99G>T p.K33N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100276778; called by muse, mutect2, varscan2
- CDKL3 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | catalogued as COSV54740945; called by muse, mutect2, varscan2
- CDKL4 | c.346T>G p.F116V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101115148; called by muse, mutect2
- CDKL5 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as rs372629988, COSV66110166; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDON | c.2834C>A p.S945Y | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55000221, COSV55000695; called by muse, mutect2, varscan2
- CDON | c.1004T>C p.V335A | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV99700837; called by muse, mutect2, varscan2
- CDRT1 | c.1926C>A p.F642L | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as COSV100599784, COSV100600022; called by muse, mutect2, varscan2
- CDYL2 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs1273478313, COSV73653976; called by muse, mutect2, varscan2
- CEACAM4 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.018); catalogued as rs1555803685, COSV99700952; called by muse, mutect2, varscan2
- CELA1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs376966959; called by muse, mutect2, varscan2
- CELA3A | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.79); PolyPhen benign (0.041); catalogued as rs1024197244, COSV99266426; called by muse, mutect2, varscan2
- CENPE | c.1642C>A p.Q548K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV54381828, COSV99477247; called by muse, mutect2, varscan2
- CENPE | c.546T>G p.I182M | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99477252; called by muse, mutect2, varscan2
- CENPF | c.1422G>T p.E474D | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100871551; called by muse, mutect2, varscan2
- CENPF | c.3598G>T p.E1200* | Nonsense Mutation (SNP) | VAF 21/37 reads (57%) | catalogued as COSV100871552, COSV65276017; called by muse, mutect2, varscan2
- CENPF | c.5919A>C p.K1973N | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV100871553; called by muse, mutect2, varscan2
- CENPJ | c.3145C>T p.R1049* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as rs757159265, COSV101121442; called by muse, mutect2, varscan2
- CENPW | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100851375; called by muse, mutect2, varscan2
- CEP135 | c.2247G>T p.K749N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.39); catalogued as COSV57258827; called by muse, mutect2, varscan2
- CEP152 | c.1137G>T p.K379N | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs1453843365, COSV57861618; called by muse, mutect2, varscan2
- CEP162 | c.927A>C p.Q309H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.814); catalogued as COSV100002466; called by muse, mutect2, varscan2
- CEP170 | c.3533C>T p.S1178L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs769903047, COSV60514056; called by muse, mutect2, varscan2
- CEP170 | c.2350G>T p.E784* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | catalogued as COSV100316642; called by muse, mutect2, varscan2
- CEP192 | c.5989C>T p.R1997C | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs746335630, COSV58059353; called by muse, mutect2, varscan2
- CEP250 | c.4263G>T p.E1421D | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100698789; called by muse, mutect2, varscan2
- CEP290 | c.6841G>T p.E2281* | Nonsense Mutation (SNP) | VAF 38/82 reads (46%) | catalogued as COSV100468049, COSV58356618; called by muse, mutect2, varscan2
- CEP290 | c.5527A>C p.I1843L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100468054; called by muse, mutect2, varscan2
- CEP290 | c.3132G>T p.K1044N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs762342726, COSV58351236; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP290 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as rs1372601569, COSV100468057; called by muse, mutect2, varscan2
- CEP350 | c.7189T>G p.F2397V | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV100854371; called by muse, mutect2, varscan2
- CEP68 | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.552); catalogued as rs1307944677, COSV53123851; called by muse, mutect2, varscan2
- CERS3 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 35/68 reads (51%) | catalogued as rs747911784, COSV52566853; called by muse, mutect2, varscan2
- CES1 | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.229); catalogued as rs1262575520, COSV100828588; called by muse, mutect2
- CETN2 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100938618; called by muse, mutect2, varscan2
- CETN2 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV100938619, COSV64743577; called by muse, varscan2
- CFAP206 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as rs377549577, COSV51535435; called by muse, mutect2, varscan2
- CFAP300 | c.336T>G p.H112Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV101462449; called by muse, mutect2, varscan2
- CFAP47 | c.1945C>T p.R649C | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); catalogued as rs113808329, COSV99934582; called by muse, mutect2, varscan2
- CFAP53 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs751078877, COSV68353065; called by muse, mutect2, varscan2
- CFAP53 | c.269T>G p.F90C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV101274961; called by muse, mutect2, varscan2
- CFAP58 | c.1759C>T p.R587* | Nonsense Mutation (SNP) | VAF 27/57 reads (47%) | catalogued as rs200198757, COSV63834955; called by muse, mutect2, varscan2
- CFAP61 | c.1036A>T p.K346* | Nonsense Mutation (SNP) | VAF 23/44 reads (52%) | catalogued as COSV99843717; called by muse, mutect2, varscan2
- CFAP61 | c.1763A>G p.Y588C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99843718; called by muse, mutect2, varscan2
- CFAP69 | c.2517C>A p.F839L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.269); catalogued as COSV60186455; called by muse, mutect2, varscan2
- CFH | c.1785C>A p.F595L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100808530, COSV66412647; called by muse, mutect2
- CFHR4 | c.104A>G p.Y35C (on ENST00000367416 / NM_001201551.2; = p.Y36C on NM_006684.5) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.815); catalogued as COSV52236912; called by muse, mutect2, varscan2
- CFHR4 | c.1078C>A p.Q360K (on ENST00000367416 / NM_001201551.2; = p.Q114K on NM_006684.5) | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.119); catalogued as COSV99259765; called by muse, mutect2, varscan2
- CFHR4 | c.1444G>A p.V482I (on ENST00000367416 / NM_001201551.2; = p.V236I on NM_006684.5) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52229076, COSV99259766; called by muse, mutect2, varscan2
- CFHR5 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs774353375, COSV56817855; called by muse, mutect2, varscan2
- CFHR5 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 27/71 reads (38%) | catalogued as rs1035811924, COSV56823294, COSV99888176; called by muse, mutect2, varscan2
- CFLAR | c.887T>G p.F296C | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV100009151; called by muse, mutect2, varscan2
- CHD1 | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV52336710; called by muse, mutect2, varscan2
- CHD1 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV99399178; called by muse, mutect2
- CHD1L | c.2483T>G p.F828C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs782570086, COSV100787364; called by muse, mutect2, varscan2
- CHD2 | c.3215G>A p.R1072Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101244657; called by muse, mutect2, varscan2
- CHD4 | c.1676G>A p.R559Q (on ENST00000357008 / NM_001363606.2; = p.R572Q on NM_001273.5) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58904370; called by muse, mutect2, varscan2
- CHD8 | c.4994A>G p.D1665G (on ENST00000646647 / NM_001170629.2; = p.D1386G on NM_020920.4) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV100783809; called by muse, mutect2, varscan2
- CHD8 | c.4342C>T p.R1448W (on ENST00000646647 / NM_001170629.2; = p.R1169W on NM_020920.4) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs759526072, COSV63218997; called by muse, varscan2
- CHEK2 | c.1470C>A p.F490L (on ENST00000382580 / NM_001005735.2; = p.F447L on NM_007194.4) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100101235; called by muse, mutect2, varscan2
- CHL1 | c.1856A>C p.H619P (on ENST00000397491 / NM_001253387.1; = p.H635P on NM_006614.4) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs1052913020, COSV99850416; called by muse, mutect2, varscan2
- CHM | c.918G>T p.E306D | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as COSV63303102; called by muse, mutect2, varscan2
- CHORDC1 | c.473A>C p.K158T | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV100271906; called by muse, mutect2
- CHPF2 | c.2273A>G p.Q758R | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV99222889; called by muse, mutect2, varscan2
- CHRNA2 | c.1018A>G p.T340A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV99531975; called by muse, mutect2
- CHRNA6 | c.1136C>A p.A379D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV52378675, COSV52380271; called by muse, mutect2, varscan2
- CHRNB3 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.361); catalogued as rs760539559, COSV51496154; called by muse, mutect2, varscan2
- CIDEC | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs200151857, COSV61061512; called by muse, mutect2, varscan2
- CIT | c.1929G>T p.E643D | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0.011); catalogued as COSV99948757; called by muse, mutect2, varscan2
- CKAP2L | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as rs535556276, COSV56698151; called by muse, mutect2, varscan2
- CKMT1A | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 30/70 reads (43%) | catalogued as COSV100787713; called by muse, mutect2, varscan2
- CKS1B | c.15A>C p.Q5H | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV100460337; called by muse, mutect2, varscan2
- CLASP1 | c.3880C>T p.R1294* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV55332247; called by muse, mutect2, varscan2
- CLC | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs149971661; called by muse, mutect2, varscan2
- CLCA2 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as COSV100991319; called by muse, varscan2
- CLCA2 | c.2437G>T p.D813Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100991418; called by muse, mutect2, varscan2
- CLCA4 | c.725G>T p.S242I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs1375708226, COSV99760297; called by muse, mutect2, varscan2
- CLCA4 | c.1303T>G p.F435V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.309); catalogued as COSV99760299; called by muse, mutect2, varscan2
- CLCN6 | c.1982A>C p.K661T | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV100411659; called by muse, mutect2
- CLEC18B | c.941C>A p.S314Y | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100375773; called by muse, mutect2, varscan2
- CLK1 | c.488T>C p.I163T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100362166; called by muse, mutect2, varscan2
- CLK2 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs745763311, COSV100751823; called by muse, mutect2, varscan2
- CLK3 | c.581G>T p.R194I (on ENST00000395066 / NM_001130028.1; = p.R46I on NM_003992.4) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100775834, COSV61414424; called by muse, varscan2
- CLK3 | c.589T>C p.S197P (on ENST00000395066 / NM_001130028.1; = p.S49P on NM_003992.4) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100775836; called by muse, varscan2
- CLPTM1L | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757726171, COSV100306893; called by muse, mutect2, varscan2
- CLRN1 | c.256T>G p.F86V (on ENST00000327047 / NM_174878.3; = p.F10V on NM_052995.2) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV99902340; called by muse, mutect2, varscan2
- CMTR2 | c.1439C>A p.S480Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100579035; called by muse, mutect2, varscan2
- CMYA5 | c.3547G>T p.E1183* | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as rs1166057346, COSV101483725; called by muse, mutect2, varscan2
- CMYA5 | c.7732C>A p.H2578N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV101483941, COSV71405403; called by muse, mutect2, varscan2
- CNGB1 | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as COSV99201945; called by muse, mutect2, varscan2
- CNNM1 | c.2666C>T p.T889M | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs552417987, COSV63200993; called by muse, mutect2, varscan2
- CNNM4 | c.1317G>T p.K439N | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV100998616; called by mutect2, varscan2
- CNOT6 | c.1066C>A p.L356I | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.68); PolyPhen benign (0.052); catalogued as COSV56159092, COSV56161394; called by muse, mutect2, varscan2
- CNTLN | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 70/169 reads (41%) | catalogued as COSV52068057; called by muse, varscan2
- CNTLN | c.843A>C p.K281N | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99263191; called by muse, mutect2, varscan2
- CNTLN | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs1236896448, COSV99263194; called by muse, mutect2, varscan2
- CNTLN | c.2827C>A p.P943T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs755471771, COSV52069929; called by muse, varscan2
- CNTN1 | c.2911G>T p.E971* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100751077; called by muse, mutect2, varscan2
- CNTN2 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.023); catalogued as COSV100084762; called by muse, varscan2
- CNTN3 | c.494T>G p.F165C | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99723579; called by muse, mutect2, varscan2
- CNTN3 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV55161810, COSV99723580; called by muse, mutect2
- CNTN4 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.611); catalogued as rs779295042, COSV100639413, COSV61870385; called by muse, mutect2, varscan2
- CNTN5 | c.68C>A p.S23Y | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV54298591, COSV54325419; called by muse, mutect2, varscan2
- CNTN6 | c.427C>A p.L143I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as COSV100610285; called by muse, varscan2
- CNTN6 | c.1325C>A p.S442Y | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.958); catalogued as COSV100610288; called by muse, mutect2, varscan2
- CNTN6 | c.2964A>C p.E988D | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as COSV100610291; called by muse, mutect2, varscan2
- COA8 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV56027321, COSV99914704; called by muse, mutect2, varscan2
- COCH | c.734G>A p.R245Q (on ENST00000216361 / NM_001347720.1; = p.R180Q on NM_004086.3) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369882771; called by muse, mutect2, varscan2
- COG3 | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 26/78 reads (33%) | catalogued as COSV100596422; called by muse, mutect2, varscan2
- COG4 | c.1896C>A p.F632L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1215483236, COSV99850602; called by muse, mutect2, varscan2
- COG5 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as rs1449966934, COSV99771572; called by muse, mutect2, varscan2
- COG7 | c.1642G>T p.E548* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as COSV100207409; called by muse, mutect2, varscan2
- COL12A1 | c.6569C>A p.S2190Y | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100485549; called by muse, mutect2, varscan2
- COL14A1 | c.3358C>T p.R1120* | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as rs779378321, COSV52852069, COSV52861310; called by muse, mutect2, varscan2
- COL14A1 | c.4421G>A p.G1474E | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99918337; called by muse, mutect2, varscan2
- COL19A1 | c.329G>T p.R110I | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100505520; called by muse, varscan2
- COL22A1 | c.2751C>A p.N917K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.042); catalogued as COSV57338112; called by muse, mutect2, varscan2
- COL24A1 | c.489G>A p.W163* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100993022; called by muse, mutect2
- COL25A1 | c.1958A>G p.Q653R | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV101212273; called by muse, mutect2, varscan2
- COL5A1 | c.5455G>A p.D1819N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100879632; called by muse, mutect2, varscan2
- COL5A2 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100880068; called by muse, varscan2
- COL6A3 | c.6514G>T p.E2172* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99796558; called by muse, mutect2, varscan2
- COL6A3 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs905662421, COSV55087815, COSV55109749; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.4429C>T p.L1477F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1021489884, COSV100649964; called by muse, mutect2
- COL8A1 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs755896312, COSV53732750; called by muse, mutect2, varscan2
- COL9A1 | c.1651A>C p.M551L | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV100294230; called by muse, mutect2, varscan2
- COL9A2 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as COSV101025613; called by muse, mutect2, varscan2
- COLEC10 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs749003411, COSV60520961; called by muse, mutect2, varscan2
- COP1 | c.2096T>G p.F699C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100442903; called by muse, mutect2, varscan2
- COPS2 | c.1298C>A p.S433Y | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV54644527; called by muse, mutect2, varscan2
- COPS3 | c.341G>T p.R114I | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.109); catalogued as COSV99253514; called by muse, mutect2, varscan2
- COPS4 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100018414; called by muse, mutect2, varscan2
- COPS6 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); catalogued as COSV57995409; called by muse, mutect2, varscan2
- COPS6 | c.906G>T p.M302I | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100384757; called by muse, mutect2, varscan2
- COQ10B | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs776608625, COSV55836205; called by muse, mutect2, varscan2
- COQ3 | c.590G>T p.R197I | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs771820402, COSV99632585, COSV99633069; called by muse, mutect2, varscan2
- CORIN | c.2656C>T p.R886* | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as rs566304016, COSV99903118; called by muse, mutect2, varscan2
- CORIN | c.2402G>T p.R801M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99903121; called by muse, mutect2, varscan2
- CORIN | c.1280G>T p.R427I | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99903122, COSV99904462; called by muse, mutect2, varscan2
- CORO1C | c.1071C>A p.F357L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV54598464, COSV99775796; called by muse, mutect2, varscan2
- CORO1C | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54596194, COSV99775799; called by muse, mutect2, varscan2
- CORO6 | c.1076A>C p.Q359P | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100801153; called by muse, mutect2, varscan2
- CPAMD8 | c.595G>A p.V199I (on ENST00000651564; = p.V152I on NM_015692.5) | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.058); catalogued as rs533642927, COSV99359064; called by muse, mutect2, varscan2
- CPB1 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as rs773201206, COSV51572057; called by muse, mutect2, varscan2
- CPB1 | c.1063A>T p.I355F | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99294134; called by muse, mutect2
- CPD | c.2890G>T p.E964* | Nonsense Mutation (SNP) | VAF 43/75 reads (57%) | catalogued as COSV99852554; called by muse, mutect2, varscan2
- CPLANE1 | c.7647G>T p.K2549N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99949912; called by muse, mutect2, varscan2
- CPLX2 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs772923966, COSV64002560; called by muse, mutect2, varscan2
- CPM | c.473A>C p.D158A | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100614953; called by muse, mutect2, varscan2
- CPNE4 | c.884C>A p.S295Y | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV70196344; called by muse, mutect2, varscan2
- CPO | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs771123911, COSV55939687, COSV55939879; called by muse, mutect2, varscan2
- CPS1 | c.1386G>T p.M462I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV99242402; called by muse, mutect2
- CPT1C | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs759980211, COSV99773296; called by muse, mutect2, varscan2
- CPVL | c.851T>G p.F284C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as COSV99605468; called by muse, mutect2, varscan2
- CR1 | c.6050C>A p.S2017Y | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100887425; called by muse, mutect2, varscan2
- CR1L | c.1316C>A p.S439Y | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs781270454, COSV54326087; called by muse, mutect2, varscan2
- CRACD | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1412215549, COSV51727945; called by muse, mutect2, varscan2
- CROT | c.854T>C p.V285A | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs766970991, COSV100519402; called by muse, varscan2
- CRYM | c.945A>C p.*315Yext*5 | Nonstop Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as CM030214, COSV99561626; called by muse, mutect2, varscan2
- CRYZL1 | c.895A>T p.K299* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV99280858; called by muse, mutect2, varscan2
- CSF2RB | c.307T>G p.F103V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99453375; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1116C>A p.F372L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.81); catalogued as COSV65676406; called by muse, mutect2, varscan2
- CSMD1 | c.8422C>T p.R2808C (on ENST00000520002; = p.R2807C on NM_033225.6) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267601889, COSV59294672; called by mutect2, varscan2
- CSMD1 | c.6738C>A p.F2246L (on ENST00000520002; = p.F2245L on NM_033225.6) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.977); catalogued as COSV100144991; called by muse, mutect2, varscan2
- CSMD3 | c.6406G>T p.D2136Y (on ENST00000297405 / NM_001363185.1; = p.D2032Y on NM_052900.3) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99827675, COSV99830696; called by muse, varscan2
- CSMD3 | c.4066G>T p.D1356Y (on ENST00000297405 / NM_001363185.1; = p.D1252Y on NM_052900.3) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99827678; called by muse, mutect2, varscan2
- CSMD3 | c.3478A>G p.I1160V (on ENST00000297405 / NM_001363185.1; = p.I1056V on NM_052900.3) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV99827682; called by muse, mutect2, varscan2
- CSNK2A2 | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99345214; called by muse, mutect2, varscan2
- CSPG4 | c.4499C>T p.T1500M | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.287); catalogued as rs760413681, COSV100413558; called by muse, mutect2, varscan2
- CSTF2 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100802924; called by muse, mutect2, varscan2
- CSTF3 | c.259-1G>A p.X87_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100123823; called by muse, mutect2, varscan2
- CTAGE1 | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV101194464; called by muse, mutect2, varscan2
- CTAGE6 | c.1055T>G p.L352R | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV101417821; called by muse, mutect2, varscan2
- CTCF | c.1495C>T p.Q499* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV99864621; called by muse, mutect2, varscan2
- CTDSPL2 | c.494C>A p.S165Y | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99526628; called by muse, mutect2, varscan2
- CTNNA2 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs369970894; called by muse, mutect2, varscan2
- CTNNA2 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs753550582, COSV58139782, COSV58140798; called by muse, mutect2, varscan2
- CTNNA3 | c.1254T>G p.F418L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV101047088; called by muse, mutect2, varscan2
- CTNNB1 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62694859; called by muse, mutect2, varscan2
- CTNND2 | c.2104C>T p.R702W | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs753918436, COSV58868050, COSV58920204; called by muse, mutect2, varscan2
- CTPS1 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs753610646, COSV65451847; called by muse, mutect2, varscan2
- CTR9 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748147577, COSV63728467; called by muse, mutect2, varscan2
- CTSA | c.1332C>A p.F444L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV99509711; called by muse, mutect2, varscan2
- CTSC | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as rs1044703733, CM993137, COSV99910421; called by muse, varscan2
- CTSE | c.703G>A p.E235K (on ENST00000360218; = p.E230K on NM_001910.4) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs781829575, COSV100733511; called by muse, mutect2, varscan2
- CTSV | c.653C>A p.S218Y | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99414333; called by muse, mutect2, varscan2
- CUBN | c.3462C>A p.F1154L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100912208; called by muse, mutect2, varscan2
- CUEDC1 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs545199000, COSV100804687; called by muse, mutect2, varscan2
- CUL2 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as COSV66079515; called by muse, mutect2, varscan2
- CUL3 | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as rs766952042, COSV52367584; called by muse, mutect2, varscan2
- CUL9 | c.3442T>G p.F1148V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV99334974; called by muse, mutect2, varscan2
- CUL9 | c.3961C>T p.R1321W | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs1411887372, COSV52727084; called by muse, mutect2, varscan2
- CUTC | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762189565, COSV65081642; called by muse, mutect2, varscan2
- CUX1 | c.106G>A p.E36K (on ENST00000292535 / NM_181552.4; = p.E47K on NM_001913.5) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs1404930496, COSV52894363; called by muse, mutect2, varscan2
- CUX2 | c.968C>A p.S323* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as COSV99918914; called by muse, mutect2, varscan2
- CWC15 | c.403A>C p.K135Q | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); catalogued as COSV99688452; called by muse, mutect2, varscan2
- CWC22 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 5/76 reads (7%) | catalogued as COSV55428073; called by muse, mutect2
- CWH43 | c.2001G>T p.E667D | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV56944581; called by muse, mutect2, varscan2
- CXCL11 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs372692015, COSV60666343; called by muse, mutect2, varscan2
- CXorf38 | c.576C>A p.F192L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as COSV100010238; called by muse, mutect2, varscan2
- CXorf56 | c.582G>T p.K194N (on ENST00000536133 / NM_001170570.2; = p.K208N on NM_022101.4) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as COSV100233346; called by muse, mutect2, varscan2
- CYB5D1 | c.608T>G p.F203C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99640890; called by muse, mutect2, varscan2
- CYLC1 | c.1092G>T p.K364N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV61410919; called by muse, mutect2, varscan2
- CYP27B1 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs777588673, COSV56984268; called by muse, mutect2, varscan2
- CYP2A7 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV52505408; called by muse, mutect2, varscan2
- CYP2B6 | c.1296G>A p.G432= | Splice Region (SNP) | VAF 32/68 reads (47%) | catalogued as COSV100137355; called by muse, mutect2, varscan2
- CYP2C8 | c.1395G>T p.K465N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV64876474; called by muse, mutect2, varscan2
- CYP2C9 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs200183364, CM087577; called by muse, mutect2, varscan2
- CYP2D6 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100637256; called by muse, mutect2, varscan2
- CYP2E1 | c.90G>T p.W30C | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99428841; called by muse, varscan2
- CYP2E1 | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as rs969893824, COSV53312269; called by muse, mutect2, varscan2
- CYP39A1 | c.1059A>C p.E353D | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV99241961; called by muse, mutect2, varscan2
3,538 further variants in this file (2,635 protein-altering or splice-affecting, 798 silent, 105 other) are not listed here.
